CTSP case CTSP-AD0Z — CTSP-DLBCL1: CTSP Diffuse Large B-Cell Lymphoma (DLBCL) CALGB 50303
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c09103e8-7b31-47b1-8422-7a2af43ee186

Demographics
Sex at birth: female; Year of birth: 1937; Vital status: Alive.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; Age at diagnosis: 71.6 years (26,147 days); Method of diagnosis: Biopsy; Ann Arbor pathologic stage: Stage III; Days to last follow up: 2,261 days (6.2 years); Best overall response: Partial Response; Ann Arbor extranodal involvement: No; Double expressor lymphoma: No; Double hit lymphoma: No; International Prognostic Index (IPI): High-Intermediate Risk.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 71 kg; Height: 159 cm; BMI: 28.1.

Biospecimens (1 sample)
- Sample DLBCL11308-sample: Sample type: Tumor; Tissue type: Tumor.
